Somatic mutation profile of tumor specimen C3L-07099-05 (aliquot CPT0432990006) from CPTAC case C3L-07099, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen C3L-07099-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 922d4a0b-8ac2-4ef9-baff-885bf0fd216b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-07099-32 (Blood Derived Normal), aliquot CPT0433100002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/03c3ab4e-6f9d-4e1c-b767-827b8bb457de

The open-access MAF lists 254 somatic variants for this specimen: 183 protein-altering or splice-affecting, 59 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 174, Silent 59, Intron 8, Nonsense Mutation 4, 5'Flank 2, Nonstop Mutation 2, Frame Shift Del 1, Splice Site 1, 3'UTR 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 36/358 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACP5 | c.924G>C p.E308D | Missense Mutation (SNP) | VAF 26/381 reads (7%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV54537259; called by muse, mutect2
- ATP2B3 | c.2523G>A p.W841* | Nonsense Mutation (SNP) | VAF 44/247 reads (18%) | catalogued as rs931050005; called by muse, mutect2, varscan2
- CCKBR | c.748C>T p.R250C | Missense Mutation (SNP) | VAF 69/534 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs865919804, COSV58100422; called by muse, mutect2, varscan2
- CDH11 | c.1135G>A p.E379K | Missense Mutation (SNP) | VAF 32/540 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV51765470; called by muse, mutect2
- CDON | c.1862G>A p.G621E | Missense Mutation (SNP) | VAF 11/353 reads (3%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.608); catalogued as COSV55001380; called by muse, mutect2
- CFAP74 | c.3974C>G p.T1325S | Missense Mutation (SNP) | VAF 31/432 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.175); catalogued as rs1211635139; called by muse, mutect2
- CMYA5 | c.5379A>C p.E1793D | Missense Mutation (SNP) | VAF 52/411 reads (13%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.036); catalogued as rs1355902306; called by muse, mutect2, varscan2
- CNDP1 | c.465C>T p.D155= | Splice Region (SNP) | VAF 22/364 reads (6%) | catalogued as rs147743167; called by muse, mutect2
- CPNE4 | c.1268C>T p.S423L | Missense Mutation (SNP) | VAF 39/412 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV101456564; called by muse, mutect2
- DPYS | c.307A>G p.I103V | Missense Mutation (SNP) | VAF 31/472 reads (7%) | SIFT tolerated (0.43); PolyPhen benign (0.124); catalogued as rs748476918; called by muse, mutect2
- EIF6 | c.328T>G p.C110G | Missense Mutation (SNP) | VAF 34/638 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV55773970; called by muse, mutect2
- ELMO1 | c.5C>T p.P2L | Missense Mutation (SNP) | VAF 64/335 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1329010889; called by muse, mutect2, varscan2
- EML3 | c.2148del p.S717Afs*46 | Frame Shift Del (DEL) | VAF 40/432 reads (9%) | catalogued as COSV53871514; called by mutect2, pindel, varscan2
- ERBB4 | c.1576T>G p.F526V | Missense Mutation (SNP) | VAF 17/341 reads (5%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.87); catalogued as COSV53555013; called by muse, mutect2
- FAM71C | c.483C>A p.D161E | Missense Mutation (SNP) | VAF 18/402 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs1462157904; called by muse, mutect2
- FLG | c.293G>A p.G98E | Missense Mutation (SNP) | VAF 38/380 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.028); catalogued as rs1405351834, COSV64243521; called by muse, mutect2, varscan2
- GCNA | c.1703G>A p.R568Q | Missense Mutation (SNP) | VAF 46/242 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as rs759448717, COSV101032624; called by muse, mutect2, varscan2
- GPR179 | c.4189C>A p.Q1397K (on ENST00000621958; = p.Q1396K on NM_001004334.4) | Missense Mutation (SNP) | VAF 32/1175 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.154); catalogued as rs771605639; called by muse, mutect2
- GRM3 | c.775G>A p.V259M | Missense Mutation (SNP) | VAF 68/551 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV64467593, COSV64471496; called by muse, varscan2
- HAUS1 | c.250C>A p.P84T | Missense Mutation (SNP) | VAF 19/365 reads (5%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.731); catalogued as COSV56364243; called by muse, mutect2
- IFNA13 | c.571T>C p.*191Qext*? | Nonstop Mutation (SNP) | VAF 20/286 reads (7%) | catalogued as COSV71924525; called by muse, mutect2
- IGLV2-18 | c.158G>A p.R53H | Missense Mutation (SNP) | VAF 28/424 reads (7%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as rs753509043; called by muse, mutect2
- KCNA10 | c.415G>T p.D139Y | Missense Mutation (SNP) | VAF 35/424 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63905549; called by muse, mutect2
- KCNH4 | c.637G>T p.G213W | Missense Mutation (SNP) | VAF 16/480 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV52917998; called by muse, mutect2
- KIF1B | c.701C>G p.T234S | Missense Mutation (SNP) | VAF 20/370 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as COSV55808535; called by muse, mutect2
- KRT34 | c.361C>T p.R121W | Missense Mutation (SNP) | VAF 52/1116 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as rs765605567; called by muse, mutect2
- KRTAP19-4 | c.204G>T p.E68D | Missense Mutation (SNP) | VAF 14/338 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as COSV100478428; called by muse, mutect2
- LDB2 | c.1097A>G p.N366S | Missense Mutation (SNP) | VAF 12/363 reads (3%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as COSV100455212; called by muse, mutect2
- LHX1 | c.776G>A p.R259Q | Missense Mutation (SNP) | VAF 48/1139 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.014); catalogued as rs1429641570; called by muse, mutect2
- LMTK2 | c.4380G>T p.Q1460H | Missense Mutation (SNP) | VAF 75/584 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as COSV52004923; called by muse, mutect2, varscan2
- MAGEB6 | c.478G>C p.G160R | Missense Mutation (SNP) | VAF 26/350 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.073); catalogued as COSV100983632, COSV100983758; called by muse, mutect2
- MAGI2 | c.808C>A p.Q270K | Missense Mutation (SNP) | VAF 42/395 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.197); catalogued as COSV62639347; called by muse, mutect2, varscan2
- MAST3 | c.302C>T p.S101F | Missense Mutation (SNP) | VAF 66/356 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53219770; called by muse, mutect2, varscan2
- MMP2 | c.1243C>T p.Q415* | Nonsense Mutation (SNP) | VAF 30/526 reads (6%) | catalogued as COSV54599696; called by muse, mutect2
- NEB | c.7927G>A p.A2643T | Missense Mutation (SNP) | VAF 29/450 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1194301158, COSV99419453; called by muse, mutect2
- NEXMIF | c.3215C>G p.S1072C | Missense Mutation (SNP) | VAF 34/328 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50062805; called by muse, mutect2, varscan2
- NRBF2 | c.774C>G p.I258M | Missense Mutation (SNP) | VAF 46/415 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); catalogued as COSV53258810; called by muse, mutect2, varscan2
- OR7D4 | c.767T>G p.L256R | Missense Mutation (SNP) | VAF 60/455 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV58072901; called by muse, mutect2, varscan2
- PCDHB14 | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 22/334 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV53387647; called by muse, mutect2
- PGLYRP4 | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 42/410 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0.025); catalogued as rs745874031, COSV62835367; called by muse, mutect2, varscan2
- PKP4 | c.2519C>T p.P840L | Missense Mutation (SNP) | VAF 17/473 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1308942099; called by muse, mutect2
- PTGFR | c.545C>T p.S182L | Missense Mutation (SNP) | VAF 26/274 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.463); catalogued as COSV66114731; called by muse, mutect2, varscan2
- PTH2R | c.926T>C p.L309P | Missense Mutation (SNP) | VAF 21/392 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV55913605; called by muse, mutect2
- PTPRK | c.767G>C p.R256T | Missense Mutation (SNP) | VAF 50/500 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV63887586; called by muse, mutect2, varscan2
- RALGAPA1 | c.458G>A p.C153Y | Missense Mutation (SNP) | VAF 27/431 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs371589913; called by muse, mutect2
- RPL10A | c.465C>G p.I155M | Missense Mutation (SNP) | VAF 24/328 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs1257230797; called by muse, mutect2
- SCARA5 | c.682C>T p.R228C | Missense Mutation (SNP) | VAF 36/593 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.543); catalogued as rs775794331; called by muse, mutect2
- SCN11A | c.5129A>T p.K1710M | Missense Mutation (SNP) | VAF 36/448 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV56572956; called by muse, mutect2
- SGSM1 | c.568C>T p.H190Y | Missense Mutation (SNP) | VAF 34/524 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1364110871; called by muse, mutect2
- SHANK1 | c.4249C>T p.R1417C | Missense Mutation (SNP) | VAF 36/868 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.34); catalogued as rs1158218013; called by muse, mutect2
- SLC26A4 | c.262G>A p.V88I | Missense Mutation (SNP) | VAF 34/470 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs779745819, CM1111378, COSV55916347; called by muse, mutect2
- STAC2 | c.625C>T p.R209C | Missense Mutation (SNP) | VAF 266/723 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs181240828; called by muse, mutect2, varscan2
- SYNE1 | c.1447G>A p.E483K (on ENST00000367255 / NM_182961.4; = p.E490K on NM_033071.3) | Missense Mutation (SNP) | VAF 23/343 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.214); catalogued as rs1554768095, COSV99554670; ClinVar: uncertain significance; called by muse, mutect2
- SYT14 | c.872A>G p.N291S | Missense Mutation (SNP) | VAF 28/440 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs775364597; called by muse, mutect2
- TCHH | c.4367G>A p.R1456H | Missense Mutation (SNP) | VAF 46/486 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.893); catalogued as rs757065975; called by muse, mutect2
- THSD7B | c.3370C>A p.L1124I (on ENST00000272643; = p.L1122I on NM_001316349.2) | Missense Mutation (SNP) | VAF 26/524 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.16); catalogued as COSV55660947, COSV55738089; called by muse, mutect2
- TRIM8 | c.242T>A p.L81Q | Missense Mutation (SNP) | VAF 84/697 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV56660559; called by muse, mutect2, varscan2
- TRPC6 | c.2326C>G p.L776V | Missense Mutation (SNP) | VAF 36/568 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.17); catalogued as rs1485234280; called by muse, mutect2
- TRPM2 | c.4060C>T p.R1354W | Missense Mutation (SNP) | VAF 24/440 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs138685995; called by muse, mutect2
- TSC22D1 | c.137C>T p.T46I | Missense Mutation (SNP) | VAF 41/816 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.446); catalogued as rs1268226143; called by muse, mutect2
- WFIKKN1 | c.1097G>A p.G366D | Missense Mutation (SNP) | VAF 35/683 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1217994412; called by muse, mutect2
- ZCWPW2 | c.801A>C p.E267D | Missense Mutation (SNP) | VAF 20/292 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV67497401; called by muse, mutect2
- ZDHHC11 | c.619A>G p.R207G | Missense Mutation (SNP) | VAF 17/328 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.04); catalogued as rs1362884597; called by muse, mutect2
- ZKSCAN7 | c.143C>T p.P48L | Missense Mutation (SNP) | VAF 19/544 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.053); catalogued as COSV56272837; called by muse, mutect2
- ZNF281 | c.470A>G p.E157G | Missense Mutation (SNP) | VAF 26/558 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs753431647; called by muse, mutect2
- ZNF471 | c.142C>T p.Q48* | Nonsense Mutation (SNP) | VAF 20/240 reads (8%) | catalogued as COSV100340790; called by muse, mutect2
- ADAMTSL4 | c.1085C>A p.P362Q | Missense Mutation (SNP) | VAF 34/485 reads (7%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.641); called by muse, mutect2
- AGBL2 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 17/477 reads (4%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.007); called by muse, mutect2
- ANK3 | c.7796C>T p.T2599I | Missense Mutation (SNP) | VAF 23/588 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.922); called by muse, mutect2
- AP3B2 | c.1715A>C p.N572T | Missense Mutation (SNP) | VAF 28/481 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- ARHGEF38 | c.604G>T p.E202* | Nonsense Mutation (SNP) | VAF 23/364 reads (6%) | called by muse, mutect2
- ART1 | c.412G>T p.A138S | Missense Mutation (SNP) | VAF 43/562 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); called by muse, mutect2
- AUTS2 | c.518G>A p.R173K | Missense Mutation (SNP) | VAF 36/278 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- BIRC6 | c.10386A>T p.R3462S | Missense Mutation (SNP) | VAF 11/254 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.062); called by muse, mutect2
- BIVM-ERCC5 | c.1916C>G p.A639G | Missense Mutation (SNP) | VAF 22/310 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.713); called by muse, mutect2
- BTBD17 | c.1235C>T p.T412M | Missense Mutation (SNP) | VAF 41/743 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- CACNA1C | c.2984A>G p.K995R | Missense Mutation (SNP) | VAF 21/377 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); called by muse, mutect2
- CAPN6 | c.277C>G p.Q93E | Missense Mutation (SNP) | VAF 17/225 reads (8%) | SIFT tolerated (0.56); PolyPhen benign (0.023); called by muse, mutect2
- CCDC169 | c.625C>T p.L209F | Missense Mutation (SNP) | VAF 16/508 reads (3%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.699); called by muse, mutect2
- CDH9 | c.1018C>G p.Q340E | Missense Mutation (SNP) | VAF 22/235 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.027); called by muse, mutect2
- CFAP58 | c.2548A>G p.M850V | Missense Mutation (SNP) | VAF 28/422 reads (7%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2
- CFAP74 | c.4518A>T p.R1506S | Missense Mutation (SNP) | VAF 19/311 reads (6%) | SIFT tolerated (0.53); PolyPhen benign (0.204); called by muse, mutect2
- CNTRL | c.1769A>C p.E590A | Missense Mutation (SNP) | VAF 43/276 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); called by muse, mutect2, varscan2
- COL22A1 | c.1442G>C p.G481A | Missense Mutation (SNP) | VAF 18/247 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- COL4A3 | c.3736T>A p.S1246T | Missense Mutation (SNP) | VAF 14/413 reads (3%) | SIFT tolerated (0.55); PolyPhen benign (0.018); called by muse, mutect2
- CXCR2 | c.1073C>A p.T358N | Missense Mutation (SNP) | VAF 15/327 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.03); called by muse, mutect2
- DDX6 | c.1435G>A p.E479K | Missense Mutation (SNP) | VAF 21/354 reads (6%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.037); called by muse, mutect2
- DLX5 | c.290A>T p.Y97F | Missense Mutation (SNP) | VAF 37/621 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.125); called by muse, mutect2
- DUOX1 | c.1078G>A p.A360T | Missense Mutation (SNP) | VAF 40/510 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2
- EDEM2 | c.1355C>A p.S452Y | Missense Mutation (SNP) | VAF 42/672 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); called by muse, mutect2
- ERCC6 | c.3988A>G p.R1330G | Missense Mutation (SNP) | VAF 16/276 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2
- ERLEC1 | c.1408T>G p.L470V | Missense Mutation (SNP) | VAF 14/278 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- FAM220A | c.91A>C p.K31Q | Missense Mutation (SNP) | VAF 138/606 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- FAP | c.1427T>G p.L476R | Missense Mutation (SNP) | VAF 26/466 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- FLT1 | c.2211G>C p.K737N | Missense Mutation (SNP) | VAF 22/410 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); called by muse, mutect2
- FRMPD1 | c.1031C>A p.T344N | Missense Mutation (SNP) | VAF 21/357 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- GALNT5 | c.1057A>G p.K353E | Missense Mutation (SNP) | VAF 21/356 reads (6%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- GGA3 | c.359G>A p.S120N (on ENST00000537686 / NM_138619.4; = p.S87N on NM_014001.5) | Missense Mutation (SNP) | VAF 61/361 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- GIT1 | c.2131C>G p.R711G | Missense Mutation (SNP) | VAF 72/629 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GPR101 | c.1463C>T p.P488L | Missense Mutation (SNP) | VAF 55/316 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GRID2IP | c.910G>A p.V304I | Missense Mutation (SNP) | VAF 27/556 reads (5%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); called by muse, mutect2
- HDAC4 | c.2975T>C p.L992S | Missense Mutation (SNP) | VAF 29/468 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HNRNPH1 | c.862G>C p.G288R | Missense Mutation (SNP) | VAF 26/492 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- HSD17B4 | c.1285G>A p.V429I (on ENST00000414835 / NM_001199291.3; = p.V404I on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/243 reads (12%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- HSPD1 | c.784G>C p.E262Q | Missense Mutation (SNP) | VAF 22/494 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); called by muse, mutect2
- HUWE1 | c.9773G>A p.S3258N | Missense Mutation (SNP) | VAF 24/264 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2
- IGHV2-5 | c.104A>C p.Q35P | Missense Mutation (SNP) | VAF 25/422 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); called by muse, mutect2
- INPPL1 | c.599G>C p.G200A | Missense Mutation (SNP) | VAF 38/683 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- IRAG2 | c.382A>C p.N128H | Missense Mutation (SNP) | VAF 46/436 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- IRAG2 | c.3755-1G>A p.X1252_splice (on ENST00000636465; = p.X297_splice on NM_006152.4 and 7 other RefSeq transcripts) | Splice Site (SNP) | VAF 19/315 reads (6%) | called by muse, mutect2
- KAZN | c.146A>C p.K49T | Missense Mutation (SNP) | VAF 38/326 reads (12%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.244); called by muse, mutect2, varscan2
- KCNS1 | c.251C>T p.S84L | Missense Mutation (SNP) | VAF 72/647 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); called by muse, varscan2
- KMT2A | c.4750A>G p.K1584E | Missense Mutation (SNP) | VAF 49/329 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KRTAP2-4 | c.223C>T p.R75C | Missense Mutation (SNP) | VAF 59/644 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- LACTB2 | c.718G>C p.E240Q | Missense Mutation (SNP) | VAF 17/234 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.012); called by muse, mutect2
- LHX9 | c.1015G>A p.G339S | Missense Mutation (SNP) | VAF 44/480 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.296); called by muse, mutect2
- LRCH1 | c.2183C>T p.A728V | Missense Mutation (SNP) | VAF 13/400 reads (3%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2
- LRIT2 | c.647A>G p.K216R | Missense Mutation (SNP) | VAF 29/491 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2
- LRIT3 | c.1411G>C p.E471Q | Missense Mutation (SNP) | VAF 28/558 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2
- LTBP2 | c.3555C>G p.H1185Q | Missense Mutation (SNP) | VAF 21/390 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0.116); called by muse, mutect2
- MAP4K2 | c.2352C>G p.I784M | Missense Mutation (SNP) | VAF 27/509 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.15); called by muse, mutect2
- MAST3 | c.2012G>A p.R671H | Missense Mutation (SNP) | VAF 36/193 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- MEOX1 | c.78C>A p.H26Q | Missense Mutation (SNP) | VAF 28/598 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.062); called by muse, mutect2
- MFSD3 | c.601C>T p.H201Y | Missense Mutation (SNP) | VAF 36/738 reads (5%) | SIFT tolerated (0.61); PolyPhen benign (0.212); called by muse, mutect2
- MGME1 | c.1034A>G p.*345Wext*46 | Nonstop Mutation (SNP) | VAF 30/426 reads (7%) | called by muse, mutect2
- MIB2 | c.995G>A p.G332D | Missense Mutation (SNP) | VAF 27/747 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); called by muse, mutect2
- MICAL1 | c.1537G>C p.E513Q | Missense Mutation (SNP) | VAF 22/498 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.707); called by muse, mutect2
- MMP14 | c.1193G>C p.G398A | Missense Mutation (SNP) | VAF 33/499 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2
- MSN | c.1199A>C p.K400T | Missense Mutation (SNP) | VAF 110/316 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- MUC5B | c.14128A>G p.T4710A | Missense Mutation (SNP) | VAF 70/593 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- NLRP1 | c.1624C>G p.L542V | Missense Mutation (SNP) | VAF 38/522 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.892); called by muse, mutect2
- NLRP9 | c.1485G>C p.M495I | Missense Mutation (SNP) | VAF 39/609 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2
- NUDCD1 | c.662T>C p.I221T | Missense Mutation (SNP) | VAF 28/240 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR4S2 | c.71T>C p.V24A | Missense Mutation (SNP) | VAF 20/492 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.005); called by muse, mutect2
- OR5H14 | c.898T>C p.S300P | Missense Mutation (SNP) | VAF 19/275 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); called by muse, mutect2
- PCNT | c.6731T>A p.V2244E | Missense Mutation (SNP) | VAF 36/706 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.133); called by muse, mutect2
- PDE1C | c.2048A>G p.H683R | Missense Mutation (SNP) | VAF 18/546 reads (3%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.074); called by muse, mutect2
- PFKL | c.221C>G p.S74C | Missense Mutation (SNP) | VAF 46/512 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- PRPF18 | c.896C>A p.S299Y | Missense Mutation (SNP) | VAF 15/458 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- PTPRC | c.1997A>C p.K666T | Missense Mutation (SNP) | VAF 28/318 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- PTPRT | c.2300C>A p.T767N | Missense Mutation (SNP) | VAF 47/492 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.303); called by muse, mutect2
- RANBP2 | c.3182G>A p.S1061N | Missense Mutation (SNP) | VAF 28/484 reads (6%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2
- RCC1L | c.262G>A p.A88T | Missense Mutation (SNP) | VAF 84/648 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.245); called by muse, varscan2
- RCC1L | c.118G>C p.E40Q | Missense Mutation (SNP) | VAF 47/810 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.86); called by muse, mutect2
- RESF1 | c.4173A>C p.K1391N | Missense Mutation (SNP) | VAF 14/384 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2
- RTL1 | c.999G>T p.E333D | Missense Mutation (SNP) | VAF 29/529 reads (5%) | SIFT tolerated (0.95); PolyPhen benign (0); called by muse, mutect2
- RUNDC1 | c.13G>C p.E5Q | Missense Mutation (SNP) | VAF 30/522 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2
- SCNN1D | c.616G>C p.G206R (on ENST00000338555; = p.G370R on NM_001130413.4) | Missense Mutation (SNP) | VAF 28/568 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- SCX | c.14C>A p.T5K | Missense Mutation (SNP) | VAF 69/382 reads (18%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC43A1 | c.789G>C p.Q263H | Missense Mutation (SNP) | VAF 34/669 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.863); called by muse, mutect2
- SLCO4C1 | c.369T>A p.N123K | Missense Mutation (SNP) | VAF 12/314 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); called by muse, mutect2
- SMARCA2 | c.3337A>T p.N1113Y | Missense Mutation (SNP) | VAF 34/347 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SMC3 | c.2132T>C p.I711T | Missense Mutation (SNP) | VAF 10/298 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); called by muse, mutect2
- SMG6 | c.1515C>A p.D505E | Missense Mutation (SNP) | VAF 26/438 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2
- SP8 | c.983G>T p.G328V (on ENST00000361443 / NM_198956.4; = p.G346V on NM_182700.6) | Missense Mutation (SNP) | VAF 42/966 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- SPEG | c.2227T>C p.C743R | Missense Mutation (SNP) | VAF 16/554 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2
- SPPL3 | c.875C>T p.A292V | Missense Mutation (SNP) | VAF 31/609 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0.315); called by muse, mutect2
- ST8SIA2 | c.782A>G p.K261R | Missense Mutation (SNP) | VAF 45/636 reads (7%) | PolyPhen benign (0.188); called by muse, mutect2
- STARD10 | c.615G>T p.Q205H | Missense Mutation (SNP) | VAF 22/417 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.052); called by muse, mutect2
- STK24 | c.205C>G p.L69V | Missense Mutation (SNP) | VAF 19/454 reads (4%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); called by muse, mutect2
- STK35 | c.458G>C p.R153P | Missense Mutation (SNP) | VAF 41/918 reads (4%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.878); called by muse, mutect2
- SYNE1 | c.13217A>T p.K4406M (on ENST00000367255 / NM_182961.4; = p.K4335M on NM_033071.3) | Missense Mutation (SNP) | VAF 28/516 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); called by muse, mutect2
- TAP1 | c.209G>T p.R70L | Missense Mutation (SNP) | VAF 59/1036 reads (6%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.012); called by muse, mutect2
- TM6SF2 | c.957C>G p.H319Q | Missense Mutation (SNP) | VAF 25/529 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- TMEM200A | c.1456A>G p.T486A | Missense Mutation (SNP) | VAF 12/313 reads (4%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.344); called by muse, mutect2
- TPCN2 | c.611A>G p.K204R | Missense Mutation (SNP) | VAF 21/499 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.585); called by muse, mutect2
- TRPM6 | c.735C>A p.H245Q | Missense Mutation (SNP) | VAF 32/563 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- TSKU | c.487G>A p.D163N | Missense Mutation (SNP) | VAF 40/674 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.433); called by muse, mutect2
- TTC27 | c.1432A>G p.R478G | Missense Mutation (SNP) | VAF 28/398 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); called by muse, mutect2
- TTN | c.9247G>C p.E3083Q (on ENST00000591111; = p.E3037Q on NM_003319.4) | Missense Mutation (SNP) | VAF 21/535 reads (4%) | PolyPhen probably damaging (0.997); called by muse, mutect2
- XPC | c.1488C>A p.S496R | Missense Mutation (SNP) | VAF 44/632 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0.215); called by muse, mutect2
- ZFP30 | c.10G>A p.D4N | Missense Mutation (SNP) | VAF 11/265 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2
- ZFR | c.3144G>T p.R1048S | Missense Mutation (SNP) | VAF 30/523 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.013); called by muse, mutect2
- ZNF404 | c.427T>A p.Y143N | Missense Mutation (SNP) | VAF 42/386 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.394); called by muse, mutect2, varscan2
- ZNF416 | c.1679C>A p.T560K | Missense Mutation (SNP) | VAF 20/547 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.062); called by muse, mutect2
- ZNF570 | c.164T>A p.L55H | Missense Mutation (SNP) | VAF 30/292 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- ZNF692 | c.1202G>A p.S401N | Missense Mutation (SNP) | VAF 24/490 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2
- ZNF723 | c.401A>C p.K134T | Missense Mutation (SNP) | VAF 35/199 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- ZNF768 | c.1264A>T p.S422C | Missense Mutation (SNP) | VAF 19/681 reads (3%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.97); called by muse, mutect2
- ZNF827 | c.1864G>C p.E622Q | Missense Mutation (SNP) | VAF 20/386 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.063); called by muse, mutect2
- ZSCAN1 | c.437G>A p.S146N | Missense Mutation (SNP) | VAF 27/490 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.441); called by muse, mutect2
- ZSCAN4 | c.781A>T p.I261F | Missense Mutation (SNP) | VAF 31/650 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.091); called by muse, mutect2
- ACOX3 | c.2004C>T p.G668= | Silent (SNP) | VAF 22/310 reads (7%) | catalogued as rs777291758, COSV62711932; called by muse, mutect2
- ACSF2 | c.501C>T p.L167= | Silent (SNP) | VAF 22/397 reads (6%) | called by muse, mutect2
- ADCYAP1R1 | c.777C>T p.F259= | Silent (SNP) | VAF 21/553 reads (4%) | catalogued as COSV58443001; called by muse, mutect2
- BCL2A1 | c.294T>A p.I98= | Silent (SNP) | VAF 40/518 reads (8%) | called by muse, mutect2
- CACNA1I | c.3390C>T p.V1130= | Silent (SNP) | VAF 43/358 reads (12%) | called by muse, mutect2, varscan2
- CCDC17 | c.351A>G p.T117= | Silent (SNP) | VAF 39/759 reads (5%) | called by muse, mutect2
- CD28 | c.367C>T p.L123= | Silent (SNP) | VAF 34/278 reads (12%) | called by muse, mutect2, varscan2
- CELSR3 | c.1731C>T p.N577= | Silent (SNP) | VAF 70/554 reads (13%) | catalogued as COSV50876294; called by muse, mutect2, varscan2
- CHST12 | c.714C>T p.Y238= | Silent (SNP) | VAF 65/761 reads (9%) | catalogued as rs772660633; called by muse, mutect2
- CNKSR1 | c.1446C>T p.F482= (on ENST00000374253 / NM_001297647.2; = p.F475= on NM_006314.3) | Silent (SNP) | VAF 16/358 reads (4%) | catalogued as rs1045143516; called by muse, mutect2
- CREB5 | c.1287C>T p.A429= (on ENST00000357727 / NM_182898.4; = p.A422= on NM_004904.3) | Silent (SNP) | VAF 54/536 reads (10%) | catalogued as rs1413246188; called by muse, mutect2
- DBF4 | c.711C>T p.T237= | Silent (SNP) | VAF 27/224 reads (12%) | called by muse, mutect2, varscan2
- EPB41L4B | c.2646C>A p.L882= | Silent (SNP) | VAF 21/318 reads (7%) | called by muse, mutect2
- EPPK1 | c.5064C>T p.G1688= | Silent (SNP) | VAF 66/1116 reads (6%) | catalogued as rs782028422, COSV73262464; called by muse, mutect2
- F2RL3 | c.762C>T p.F254= | Silent (SNP) | VAF 110/603 reads (18%) | catalogued as rs1249182911; called by muse, varscan2
- FRYL | c.5754C>T p.L1918= | Silent (SNP) | VAF 12/434 reads (3%) | called by muse, mutect2
- GAA | c.54C>G p.L18= | Silent (SNP) | VAF 40/640 reads (6%) | called by muse, mutect2
- GABRD | c.513C>T p.Y171= | Silent (SNP) | VAF 21/580 reads (4%) | called by muse, mutect2
- GLI3 | c.2631C>T p.S877= | Silent (SNP) | VAF 68/694 reads (10%) | catalogued as COSV67889133; called by muse, mutect2
- GPR61 | c.723G>A p.Q241= | Silent (SNP) | VAF 30/615 reads (5%) | called by muse, mutect2
- HDAC4 | c.2974T>C p.L992= | Silent (SNP) | VAF 30/468 reads (6%) | called by muse, mutect2
- HNRNPUL1 | c.957C>T p.Y319= | Silent (SNP) | VAF 46/534 reads (9%) | called by muse, mutect2
- HSP90AA1 | c.63C>G p.A21= | Silent (SNP) | VAF 24/583 reads (4%) | called by muse, mutect2
- IGF1R | c.489G>A p.A163= | Silent (SNP) | VAF 34/519 reads (7%) | catalogued as rs765173001, COSV51271515; called by muse, mutect2
- INSYN2B | c.1464A>G p.E488= | Silent (SNP) | VAF 32/524 reads (6%) | catalogued as COSV56943589; called by muse, mutect2
- IQSEC3 | c.1848C>T p.S616= (on ENST00000538872 / NM_001170738.2; = p.S313= on NM_015232.1) | Silent (SNP) | VAF 78/541 reads (14%) | catalogued as rs782345940; called by muse, mutect2, varscan2
- ITIH2 | c.1635C>A p.I545= | Silent (SNP) | VAF 16/237 reads (7%) | called by muse, mutect2
- KHNYN | c.1968C>T p.I656= | Silent (SNP) | VAF 24/439 reads (5%) | catalogued as rs1258596179; called by muse, mutect2
- KLHL7 | c.57T>G p.A19= | Silent (SNP) | VAF 22/488 reads (5%) | called by muse, mutect2
- MAGEL2 | c.3006A>T p.G1002= | Silent (SNP) | VAF 52/576 reads (9%) | called by muse, mutect2
- MTNR1B | c.288A>T p.L96= | Silent (SNP) | VAF 28/530 reads (5%) | called by muse, mutect2
- NNAT | c.210T>G p.V70= (on ENST00000649309 / NM_001322802.2; = p.L72W on NM_005386.4) | Silent (SNP) | VAF 25/719 reads (3%) | called by muse, mutect2
- NPFFR2 | c.120C>T p.G40= | Silent (SNP) | VAF 47/644 reads (7%) | catalogued as COSV58147815; called by muse, mutect2
- OR10H1 | c.105C>T p.Y35= | Silent (SNP) | VAF 36/674 reads (5%) | called by muse, mutect2
- OR5L1 | c.399A>G p.T133= | Silent (SNP) | VAF 58/561 reads (10%) | catalogued as rs771338813; called by muse, mutect2
- PCDH18 | c.156T>C p.A52= | Silent (SNP) | VAF 23/480 reads (5%) | called by muse, mutect2
- PGAP3 | c.804G>T p.L268= | Silent (SNP) | VAF 46/1458 reads (3%) | called by muse, mutect2
- PGGHG | c.766C>T p.L256= | Silent (SNP) | VAF 34/681 reads (5%) | catalogued as COSV67140760; called by muse, mutect2
- PPP4R3C | c.1725C>T p.Y575= | Silent (SNP) | VAF 16/147 reads (11%) | called by muse, mutect2, varscan2
- RBL2 | c.1428A>G p.P476= | Silent (SNP) | VAF 17/373 reads (5%) | catalogued as rs1367577142; called by muse, mutect2
- SHC2 | c.1734C>T p.V578= | Silent (SNP) | VAF 80/434 reads (18%) | called by muse, mutect2, varscan2
- SIGLEC5 | c.609G>A p.R203= | Silent (SNP) | VAF 109/731 reads (15%) | called by muse, mutect2, varscan2
- SLC1A7 | c.1296C>A p.I432= | Silent (SNP) | VAF 32/603 reads (5%) | catalogued as COSV57016960; called by muse, mutect2
- SP8 | c.252C>T p.S84= (on ENST00000361443 / NM_198956.4; = p.S102= on NM_182700.6) | Silent (SNP) | VAF 40/375 reads (11%) | catalogued as rs1387940206; called by muse, varscan2
- SPATC1L | c.816G>A p.P272= (on ENST00000291672 / NM_001142854.2; = p.P118= on NM_032261.5) | Silent (SNP) | VAF 81/813 reads (10%) | catalogued as rs370174813; called by muse, mutect2
- SRP68 | c.1113G>A p.G371= | Silent (SNP) | VAF 16/287 reads (6%) | called by muse, mutect2
- STK32C | c.1167C>A p.I389= | Silent (SNP) | VAF 59/428 reads (14%) | called by muse, mutect2, varscan2
- TBX2 | c.1350G>C p.L450= | Silent (SNP) | VAF 40/844 reads (5%) | called by muse, mutect2
- TGIF2LX | c.471G>A p.L157= | Silent (SNP) | VAF 54/323 reads (17%) | catalogued as COSV52213400; called by muse, mutect2, varscan2
- TGM6 | c.1743G>A p.K581= | Silent (SNP) | VAF 32/564 reads (6%) | called by muse, mutect2
- TMEM132B | c.1701C>T p.H567= | Silent (SNP) | VAF 36/590 reads (6%) | catalogued as rs532155301, COSV54753684; called by muse, mutect2
- TRPA1 | c.1938A>T p.T646= | Silent (SNP) | VAF 14/261 reads (5%) | called by muse, mutect2
- TSNARE1 | c.951G>A p.K317= | Silent (SNP) | VAF 16/557 reads (3%) | called by muse, mutect2
- TUBD1 | c.1281A>G p.T427= | Silent (SNP) | VAF 16/294 reads (5%) | called by muse, mutect2
- UBE2L5 | c.441T>C p.Y147= | Silent (SNP) | VAF 48/289 reads (17%) | catalogued as rs907225691; called by muse, mutect2, varscan2
- VAX2 | c.333C>T p.A111= | Silent (SNP) | VAF 23/540 reads (4%) | catalogued as rs782446663, COSV99313623; called by muse, mutect2
- VWF | c.3891G>A p.K1297= | Silent (SNP) | VAF 32/622 reads (5%) | called by muse, mutect2
- WDR97 | c.4785G>A p.P1595= | Silent (SNP) | VAF 86/596 reads (14%) | catalogued as rs1332107157; called by muse, mutect2, varscan2
- ZMYND8 | c.450C>T p.T150= (on ENST00000311275 / NM_001363741.2; = p.T170= on NM_012408.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/529 reads (4%) | catalogued as rs1320039760; called by muse, mutect2
- CACNA1C | c.3829-643T>G | Intron (SNP) | VAF 32/518 reads (6%) | catalogued as COSV59751484; called by muse, mutect2
- CCDC74B | c.295+160G>T | Intron (SNP) | VAF 61/695 reads (9%) | catalogued as rs767671150; called by muse, mutect2
- KIR3DX1 | n.388C>A | RNA (SNP) | VAF 40/351 reads (11%) | called by muse, mutect2, varscan2
- LTN1 | c.2163+1111C>T | Intron (SNP) | VAF 30/333 reads (9%) | catalogued as rs1245606473; called by muse, mutect2
- NLRP7 | c.2810+2768G>A | Intron (SNP) | VAF 34/759 reads (4%) | catalogued as COSV100051717; called by muse, mutect2
- NPDC1 | c.113-57G>A | Intron (SNP) | VAF 62/652 reads (10%) | catalogued as rs908879684; called by muse, mutect2
- NRG1 | chr8:31639411 C>T | 5'Flank (SNP) | VAF 41/433 reads (9%) | called by muse, mutect2
- PLOD2 | c.1128-80A>G | Intron (SNP) | VAF 17/170 reads (10%) | catalogued as rs757178677; called by muse, mutect2
- PTK2 | c.2946+2133A>C | Intron (SNP) | VAF 47/327 reads (14%) | called by muse, mutect2, varscan2
- SMARCA5 | chr4:143513637 T>A | 5'Flank (SNP) | VAF 24/466 reads (5%) | called by muse, mutect2
- SRL | c.*1688A>T | 3'UTR (SNP) | VAF 23/478 reads (5%) | called by muse, mutect2
- ZNF8 | c.66+168G>C | Intron (SNP) | VAF 39/843 reads (5%) | called by muse, mutect2
